Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7413, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7413-01A (Primary Tumor).

DIAGNOSIS :

(A) ANTERIOR MANDIBLE:

MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA INVADING ANTERIOR
MANDIBLE, RESECTION MARGINS FREE OF TUMOR.

DIAGNOSIS

**(A) CHIN INCLUDING ANTERIOR MANDIBLE AND OVERLYING SKIN AND BASE OF TONGUE,
RESECTION:**

INVASIVE, MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA INVOLVING
SKIN, SUBCUTANEOUS TISSUE AND FLOOR OF MOUTH, RESECTION MARGINS
FREE OF TUMOR.

Sections of bone pending decalcification.

(B) RIGHT LINGUAL NERVE:

Peripheral nerve, no evidence of carcinoma.

(C) LYMPH NODES, RIGHT MIDDLE JUGULAR:

Lymph nodes, no evidence of metastatic disease.

COMMENT

Perineural and lymphovascular invasion are not seen.

SPECIMEN

**(A) CHIN INCLUDING ANTERIOR MANDIBLE AND OVERLYING SKIN AND BASE OF TONGUE,
(B) RIGHT LINGUAL NERVE:**

(C) LYMPH NODES, RIGHT MIDDLE JUGULAR:

SNOMED CODES

T-11180,M-80703

Source: NCI Genomic Data Commons file 6a0ce38e-40b2-4ba5-98f2-442ff524f707 (TCGA-CV-7413.75B017A7-C3E9-4EB1-8FD7-99B419889861.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).